Somatic mutation profile of tumor specimen TCGA-DX-AB32-01A (aliquot TCGA-DX-AB32-01A-11D-A417-09) from TCGA case TCGA-DX-AB32, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 51.0 years (18,631 days).
Specimen TCGA-DX-AB32-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faf6da65-e002-44f8-be8e-6d7de424ef47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB32-10A (Blood Derived Normal), aliquot TCGA-DX-AB32-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a49846-ddf8-4b0d-9981-b59e6adf06fd

The open-access MAF lists 319 somatic variants for this specimen: 221 protein-altering or splice-affecting, 91 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 91, Nonsense Mutation 12, Frame Shift Del 9, Splice Site 3, Intron 3, Frame Shift Ins 2, Splice Region 2, 3'UTR 1, In Frame Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPYD | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs141597515, CM147508; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GLRA1 | c.1283G>A p.R428H (on ENST00000455880 / NM_001146040.2; = p.R420H on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281864919, CM992338, COSV51015038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCAL1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119473037, CM020313, COSV61921141; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.754_756del p.L252del | In Frame Del (DEL) | VAF 7/27 reads (26%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACAN | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780224333, COSV61358499; called by muse, mutect2, varscan2
- ACVR2B | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1484586588, COSV61701024; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs758805875, COSV101001040; called by muse, mutect2, varscan2
- ADARB2 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs151300637; called by muse, mutect2, varscan2
- ADGRB1 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV60099409; called by muse, mutect2, varscan2
- AHNAK2 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.111); catalogued as COSV100314895; called by muse, mutect2, varscan2
- AKT2 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV100251289; called by muse, mutect2, varscan2
- ALDOB | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs565827286, COSV100878793; called by muse, mutect2, varscan2
- AMPD1 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100814780; called by muse, mutect2, varscan2
- AP1M2 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51567312, COSV51568010; called by muse, mutect2, varscan2
- ARHGEF2 | c.1411C>T p.R471C (on ENST00000361247 / NM_001162383.2; = p.R443C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58106417; called by muse, mutect2, varscan2
- ARMC3 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs750668869, COSV53065091, COSV53066211; called by muse, varscan2
- ATAD5 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs780919433, COSV100429529; called by muse, mutect2, varscan2
- B4GALT3 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV60526858; called by muse, mutect2
- BCAM | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs777424090, COSV99538401; called by muse, mutect2, varscan2
- BCL6B | c.1326C>T p.C442= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as rs1175388791, COSV53427821; called by muse, mutect2, varscan2
- BDKRB1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371690606; called by muse, mutect2, varscan2
- BLMH | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99912974; called by muse, mutect2, varscan2
- BLVRB | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99647804; called by muse, varscan2
- C1S | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV100196270; called by muse, mutect2, varscan2
- C1orf21 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1214002374, COSV99333767; called by muse, mutect2, varscan2
- C3orf38 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 99/136 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs199859699, COSV100007277; called by muse, mutect2, varscan2
- CACNA1B | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751010507, COSV53136179, COSV99494357; called by muse, mutect2, varscan2
- CACNA1I | c.5650C>T p.R1884C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs183581233, COSV60800456; called by muse, mutect2, varscan2
- CCDC116 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.43); catalogued as rs566751888, COSV99488777; called by muse, mutect2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC42 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV99549613; called by muse, mutect2, varscan2
- CCDC87 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100039662; called by muse, mutect2, varscan2
- CCT3 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs777799358, COSV99826997; called by muse, mutect2, varscan2
- CDHR5 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100363154; called by muse, mutect2, varscan2
- CDIPT | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs150782987; called by muse, mutect2, varscan2
- CELSR3 | c.6257C>T p.S2086L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs925693869, COSV99372127, COSV99373066; called by muse, mutect2, varscan2
- CFH | c.963del p.L322* | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as COSV62777815; called by mutect2, pindel, varscan2
- CHRM1 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV61006050; called by muse, mutect2, varscan2
- COL1A1 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs979875280, COSV99866074; called by muse, mutect2, varscan2
- CPB1 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99294014; called by muse, mutect2, varscan2
- CRACD | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763160970, COSV99948265; called by muse, mutect2, varscan2
- CTDP1 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs139811552; called by muse, mutect2, varscan2
- CYFIP2 | c.2425A>G p.S809G (on ENST00000616178 / NM_001291722.2; = p.S784G on NM_014376.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV100555327; called by muse, mutect2, varscan2
- CYLC2 | c.747del p.D250Mfs*106 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as COSV100872458; called by mutect2, pindel, varscan2
- DAB1 | c.1100C>T p.P367L (on ENST00000371231; = p.P334L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs770270572, COSV100976106; called by mutect2, varscan2
- DDX51 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370925243; called by muse, mutect2, varscan2
- DEDD | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100919008; called by muse, mutect2, varscan2
- DENND11 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1286236741, COSV101530686, COSV101530698; called by muse, mutect2, varscan2
- DGKE | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs1480696814, COSV99400616; called by muse, mutect2, varscan2
- DHX37 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376228891; called by muse, mutect2, varscan2
- DLEC1 | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100341084; called by muse, varscan2
- DSCAM | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258623, COSV68024366; called by muse, mutect2, varscan2
- DSCC1 | c.486+1G>A p.X162_splice | Splice Site (SNP) | VAF 37/139 reads (27%) | catalogued as COSV100558188; called by muse, mutect2, varscan2
- DSP | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101131148; called by muse, mutect2, varscan2
- DTX1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs1487069789, COSV99986063; called by muse, mutect2, varscan2
- DTYMK | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1314382660, COSV99994631; called by muse, mutect2, varscan2
- DUOX1 | c.4409T>C p.I1470T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99334122; called by muse, mutect2, varscan2
- EHMT2 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs768623940, COSV100977080; called by muse, mutect2, varscan2
- EPC1 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs377321302; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- FAAP20 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66032053; called by muse, mutect2, varscan2
- FABP4 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99808432; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD5 | c.3286C>G p.H1096D | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV99546990; called by muse, varscan2
- FGF3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs782226740, COSV61925288; called by muse, mutect2, varscan2
- FIGLA | c.586A>T p.I196F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100189607; called by muse, mutect2, varscan2
- FMOD | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs755928134, COSV100724456; called by muse, mutect2, varscan2
- FN1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100115383; called by muse, mutect2, varscan2
- FOXJ3 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759553757, COSV100691333; called by muse, mutect2
- FRMPD3 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.208); catalogued as rs971861976, COSV99345372; called by muse, mutect2, varscan2
- FRYL | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99975213; called by muse, mutect2, varscan2
- FXR1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59767765; called by muse, mutect2, varscan2
- GBA2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs192753525, COSV100960030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBF1 | c.2530C>T p.R844C (on ENST00000369983 / NM_001377137.1; = p.R843C on NM_004193.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756551462, COSV100890230; called by muse, mutect2, varscan2
- GLIS2 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99267221; called by muse, mutect2, varscan2
- GPCPD1 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100980045; called by muse, mutect2, varscan2
- HAPLN4 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891875500, COSV52268956; called by muse, mutect2, varscan2
- HMCN1 | c.16129C>A p.P5377T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV54904449, COSV99622187; called by muse, mutect2, varscan2
- HMGCS2 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs773945291, COSV65567390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HPS4 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs139039617; called by muse, mutect2, varscan2
- HYKK | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100856398; called by muse, mutect2, varscan2
- IGHA1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372490697; called by muse, mutect2, varscan2
- IGKV2D-30 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs1384398071; called by muse, mutect2, varscan2
- INSC | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766025835, COSV101088613; called by mutect2, varscan2
- INSL4 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs150771132; called by muse, mutect2, varscan2
- ITGA10 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782567617, COSV65197736; called by muse, mutect2, varscan2
- ITPR2 | c.3167C>T p.T1056M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.033); catalogued as rs369024488; called by muse, mutect2, varscan2
- KANK2 | c.2362G>A p.A788T (on ENST00000586659 / NM_001379562.1; = p.A796T on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368328659; called by muse, mutect2, varscan2
- KCNC4 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100873552; called by muse, mutect2
- KCNQ2 | c.1489C>T p.R497C (on ENST00000359125 / NM_172107.4; = p.R469C on NM_004518.6) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs540461827, COSV60540380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM2A | c.1852G>T p.V618F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100445338; called by muse, mutect2
- KIF14 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs754537198, COSV100950544; called by muse, mutect2, varscan2
- KIF23 | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs1477360558, COSV52978189; called by muse, mutect2, varscan2
- KIF3B | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100996276; called by muse, mutect2, varscan2
- KIF4B | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs759136573, COSV70527082, COSV70528453; called by muse, mutect2, varscan2
- KIFAP3 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs762221012, COSV100846643; called by muse, mutect2, varscan2
- KMT2D | c.16183T>C p.W5395R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99976374; called by muse, mutect2, varscan2
- LATS2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1326904339, COSV66878994; called by muse, mutect2, varscan2
- LENG8 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs778461503, COSV100457029; called by muse, mutect2, varscan2
- LRP1B | c.10228A>G p.I3410V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101249538; called by muse, mutect2, varscan2
- LRP1B | c.5869G>T p.G1957W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101249540; called by muse, mutect2, varscan2
- LRRC34 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100336175; called by muse, mutect2, varscan2
- LRRC49 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99536751; called by muse, mutect2, varscan2
- LSM11 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as rs780925045, COSV99643818; called by muse, mutect2, varscan2
- MAMDC2 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368156190; called by muse, mutect2, varscan2
- MAN1A1 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63787291; called by muse, mutect2, varscan2
- MAN2B2 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.135); catalogued as rs186250763; called by muse, mutect2, varscan2
- MAP3K13 | c.1366C>G p.R456G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV53983347, COSV53988799, COSV99406123; called by muse, mutect2, varscan2
- MAP3K6 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs376352782; called by muse, mutect2, varscan2
- MAP3K6 | c.847T>C p.S283P | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100708977; called by muse, mutect2, varscan2
- MCM4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs980723406, COSV100031107; called by muse, mutect2, varscan2
- MGAM | c.3668A>G p.E1223G | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV101527329; called by muse, mutect2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by muse, mutect2, varscan2
- MINDY3 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV99510374; called by muse, mutect2, varscan2
- MMP19 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762888609, COSV59450393; called by muse, mutect2, varscan2
- MORC3 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs545559328, COSV101264791; called by muse, mutect2, varscan2
- MPDZ | c.3508C>T p.R1170* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs200131423; called by muse, mutect2, varscan2
- MR1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs763962565, COSV99294733; called by muse, mutect2, varscan2
- MRPS30 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs751273694, COSV50181746, COSV99138124; ClinVar: not provided; called by muse, mutect2, varscan2
- MTHFD2L | c.230T>C p.L77P (on ENST00000395759 / NM_001144978.2; = p.L19P on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.53); catalogued as COSV100305712; called by muse, mutect2, varscan2
- MYO7A | c.3836C>T p.T1279M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766245260, COSV101289001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV101261053; called by muse, mutect2, varscan2
- MYT1L | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101216703, COSV101217154; called by muse, mutect2, varscan2
- NEDD4 | c.1616T>C p.L539S (on ENST00000508342 / NM_001284338.1; = p.L120S on NM_006154.4) | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100163114; called by muse, mutect2, varscan2
- NGFR | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs748153154, COSV99412584; called by muse, mutect2, varscan2
- NLRP2 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs143361632; called by muse, mutect2, varscan2
- NUP54 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99345044; called by muse, mutect2, varscan2
- ODR4 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1367585648, COSV99834081; called by muse, mutect2, varscan2
- OR5V1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101011044, COSV65830554; called by muse, mutect2, varscan2
- OR6N1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625010; called by mutect2, varscan2
- OR7G3 | c.565T>C p.C189R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1366161358, COSV100555575; called by muse, mutect2, varscan2
- OSBPL10 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs751308846, COSV101158686; called by muse, mutect2, varscan2
- OVCH2 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV101491844; called by muse, mutect2, varscan2
- PCDH1 | c.3081dup p.K1028Qfs*49 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs776686446; called by mutect2, varscan2
- PCDHA10 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782689818, COSV100246804, COSV56528090; called by muse, mutect2, varscan2
- PCM1 | c.4540G>A p.V1514M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753455636, COSV100278710; called by muse, mutect2, varscan2
- PDCD11 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as rs566526072, COSV100874205; called by muse, mutect2, varscan2
- PDSS1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs759110650, COSV100697640; called by muse, mutect2, varscan2
- PKN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54404761; called by muse, mutect2, varscan2
- PLD5 | c.1588G>A p.G530R (on ENST00000442594; = p.G468R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs150166315; called by muse, mutect2, varscan2
- PLTP | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100819015; called by muse, mutect2, varscan2
- PLXNA1 | c.4869C>T p.Y1623= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as rs774909770, COSV52533071; called by muse, mutect2, varscan2
- POLR3E | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1252985120, COSV100241807; called by muse, mutect2, varscan2
- PPFIA4 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99829356; called by muse, mutect2, varscan2
- PPP1R16A | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as rs758715057, COSV99477282; called by muse, mutect2, varscan2
- PRAMEF12 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs369283541; called by muse, mutect2, varscan2
- PRDM1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs367766895; called by muse, mutect2, varscan2
- PRDM10 | c.1848C>G p.F616L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100456506; called by muse, mutect2, varscan2
- PRLHR | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs754718370, COSV53303414; called by muse, mutect2, varscan2
- PRPF6 | c.1123A>T p.I375F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99411022; called by muse, mutect2, varscan2
- PSG2 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs1202253461, COSV101290455; called by muse, mutect2, varscan2
- PTPN4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1186373089, COSV55298093, COSV99750484; called by muse, mutect2
- PTPN5 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100659542; called by muse, mutect2, varscan2
- PTPRB | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs376975449; called by muse, mutect2, varscan2
- RBM17 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101158995; called by muse, mutect2, varscan2
- RELL2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.869); catalogued as rs139014914; called by muse, mutect2, varscan2
- RFPL1 | c.752T>C p.M251T | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs768518577, COSV100585550; called by muse, mutect2, varscan2
- RICTOR | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs762282621, COSV99704094; called by muse, mutect2, varscan2
- RPN2 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99411290; called by muse, mutect2, varscan2
- RPTN | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100285149; called by muse, mutect2, varscan2
- RXRG | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63231584; called by muse, mutect2, varscan2
- RYR2 | c.11218G>T p.V3740L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs536555602, COSV100767080, COSV63686746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs766905615, COSV73306684; called by muse, mutect2, varscan2
- SAMHD1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs766842258, COSV53431786; called by muse, mutect2, varscan2
- SFMBT2 | c.2308G>A p.V770M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs775887528, COSV62804941; called by muse, mutect2, varscan2
- SH2D3A | c.262A>T p.I88L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99837723; called by muse, mutect2, varscan2
- SIGLEC7 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771229132, COSV99978326; called by muse, mutect2, varscan2
- SLC38A1 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101284092, COSV67064551; called by muse, mutect2, varscan2
- SLC5A11 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100762618; called by muse, mutect2, varscan2
- SLC5A2 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs535031004, COSV100392922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNRNP200 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs371058559; called by muse, mutect2, varscan2
- SP3 | c.2084A>G p.H695R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100021378; called by muse, mutect2, varscan2
- SP4 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as rs763993457, COSV99753814; called by muse, mutect2, varscan2
- SPACA9 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050827; called by muse, mutect2, varscan2
- SRP68 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100325876; called by muse, mutect2, varscan2
- STAB1 | c.5543G>A p.R1848Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs918534801, COSV100194403; called by muse, mutect2, varscan2
- STON2 | c.2183G>A p.R728Q (on ENST00000649389 / NM_001366849.2; = p.R671Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs760033415, COSV99964247, COSV99964663; called by muse, mutect2, varscan2
- STXBP5L | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197390578, COSV56513541; called by muse, mutect2, varscan2
- SVOPL | c.1321A>C p.I441L (on ENST00000419765; = p.I289L on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99938919; called by muse, mutect2
- SYNCRIP | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100784265, COSV62288784; called by muse, mutect2, varscan2
- SYNE1 | c.730A>G p.T244A (on ENST00000367255 / NM_182961.4; = p.T251A on NM_033071.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs755005602, COSV99549339; called by muse, mutect2, varscan2
- SYNE2 | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV58359009; called by muse, mutect2, varscan2
- SYNJ1 | c.968G>T p.R323M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448760; called by muse, mutect2, varscan2
- TBX4 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs371242130; called by muse, mutect2, varscan2
- TELO2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs758024477, COSV51981213; called by muse, mutect2, varscan2
- TENT2 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as rs775713016, COSV99706132; called by muse, mutect2, varscan2
- TFAP4 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99200019; called by muse, mutect2
- TKTL2 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs1407591948, COSV99760952; called by muse, mutect2, varscan2
- TMEM63B | c.1609C>A p.L537M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99440811; called by muse, mutect2, varscan2
- TMPRSS7 | c.1138A>G p.K380E (on ENST00000452346; = p.K254E on NM_001042575.2) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.216); catalogued as COSV101340037; called by muse, mutect2, varscan2
- TNRC18 | c.8090C>T p.A2697V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs754507459, COSV100078454; called by muse, mutect2, varscan2
- TOP3B | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100592237; called by muse, mutect2, varscan2
- TPSG1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs146886017; called by muse, mutect2, varscan2
- TRIOBP | c.6859C>T p.R2287C (on ENST00000644935 / NM_001039141.3; = p.R574C on NM_007032.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746244521, COSV100730480; called by muse, mutect2, varscan2
- TSC2 | c.2674G>A p.V892I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs376801256, COSV54773672; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSEN54 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs754047235, COSV51400875; called by muse, mutect2, varscan2
- TSSC4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs747882180, COSV50144375; called by muse, mutect2, varscan2
- TTC13 | c.1180A>G p.S394G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as COSV100792820; called by muse, mutect2, varscan2
- UBL3 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV101041496; called by muse, mutect2, varscan2
- UBXN6 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as rs151060057; called by muse, mutect2, varscan2
- UGGT2 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140859099; called by muse, mutect2, varscan2
- UGT2B15 | c.874-2A>G p.X292_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100592165; called by mutect2, varscan2
- ULK1 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as rs374570609; called by muse, mutect2, varscan2
- UMPS | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377750200; called by muse, mutect2, varscan2
- UNC5B | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV100099934; called by muse, mutect2, varscan2
- USP36 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100361094; called by muse, mutect2, varscan2
- VIRMA | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52589461; called by muse, mutect2, varscan2
- ZAN | c.5316G>C p.Q1772H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100768933; called by muse, mutect2
- ZMYND8 | c.901G>A p.G301R (on ENST00000311275 / NM_001363741.2; = p.G321R on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99519218; called by muse, mutect2, varscan2
- ZNF225 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as rs777217272, COSV99489198; called by muse, mutect2, varscan2
- ZNF600 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV100592862; called by muse, mutect2, varscan2
- ZNF623 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV71697208; called by muse, mutect2, varscan2
- ZNF827 | c.3220G>A p.G1074S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148875276; called by muse, mutect2, varscan2
- ZNF835 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs915967063, COSV73379200; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel, varscan2
- ADH4 | c.346del p.I116Sfs*13 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- CCDC107 | c.405del p.F135Lfs*4 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- TFCP2 | c.760del p.M254Wfs*105 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- TRDV1 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ABCA1 | c.3342C>A p.S1114= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs547738950, COSV101036311; called by muse, mutect2, varscan2
- ABCG8 | c.1644C>T p.A548= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs200018072; called by muse, mutect2
- ADCY9 | c.1899C>T p.C633= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs143099437; called by mutect2, varscan2
- AHR | c.501A>C p.R167= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99619084; called by muse, mutect2, varscan2
- ALDH4A1 | c.624G>A p.S208= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs142063145, COSV99311572; called by muse, mutect2, varscan2
- ANKRD13A | c.1563C>T p.D521= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs751762400, COSV99923785; called by muse, mutect2, varscan2
- ARID3B | c.912T>C p.C304= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100654488; called by muse, mutect2, varscan2
- ARID3B | c.1218C>A p.P406= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100654489, COSV60556545; called by muse, mutect2, varscan2
- BCHE | c.1371G>A p.P457= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs369712135; called by muse, mutect2, varscan2
- BLOC1S1 | c.357T>C p.I119= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs933468703, COSV99220995; called by muse, mutect2, varscan2
- BTBD2 | c.765G>A p.A255= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs759408613, COSV55307320; called by muse, mutect2, varscan2
- C2CD5 | c.591G>A p.S197= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs770258381, COSV100448320; called by muse, mutect2, varscan2
- CABP1 | c.858C>T p.F286= (on ENST00000316803 / NM_001033677.1; = p.F83= on NM_004276.5) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV56457881, COSV56458534; called by muse, mutect2, varscan2
- CASZ1 | c.4005C>T p.R1335= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs759487011, COSV59739094; called by muse, mutect2, varscan2
- CCDC7 | c.2349T>C p.H783= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV100177116; called by muse, mutect2, varscan2
- CD244 | c.333T>C p.S111= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV59240803; called by muse, mutect2, varscan2
- CNTNAP3 | c.2988C>T p.C996= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as COSV99903807; called by muse, mutect2, varscan2
- CORO7 | c.1620G>A p.T540= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs776723227, COSV99226962; called by muse, mutect2, varscan2
- CPA3 | c.849G>A p.T283= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs200538548, COSV56047209; called by muse, mutect2, varscan2
- CPSF6 | c.732A>C p.P244= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99878858; called by muse, mutect2, varscan2
- CSF2RA | c.246A>G p.T82= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV100817368; called by muse, mutect2, varscan2
- CYP2A7 | c.297C>T p.S99= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs112051160, COSV99394319; called by muse, mutect2, varscan2
- DTWD1 | c.189T>C p.G63= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV99233472; called by muse, mutect2, varscan2
- E4F1 | c.1866G>A p.T622= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs780354367, COSV57039210; called by muse, mutect2, varscan2
- EPHA7 | c.2010T>C p.G670= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV65188994; called by muse, mutect2, varscan2
- F5 | c.999C>A p.T333= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100888811; called by muse, mutect2, varscan2
- FRAS1 | c.9213G>T p.G3071= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99346899; called by muse, mutect2, varscan2
- GBP6 | c.246C>T p.C82= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs778373002, COSV100969426; called by muse, mutect2, varscan2
- GCC2 | c.2922C>T p.A974= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs754436218, COSV100565144, COSV100565476; called by muse, mutect2, varscan2
- GLIS2 | c.1551G>C p.L517= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99267222; called by muse, mutect2, varscan2
- GPRIN1 | c.1752G>A p.P584= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV56134708; called by muse, mutect2, varscan2
- H2BC17 | c.117T>A p.S39= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV58153297; called by muse, mutect2, varscan2
- HECTD4 | c.12774G>A p.T4258= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1240064031, COSV101106331; called by muse, mutect2
- INA | c.1206C>T p.G402= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs1368516348, COSV100878542; called by muse, mutect2, varscan2
- ITGA7 | c.1623C>T p.G541= (on ENST00000555728; = p.G497= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs780808115, COSV99144126; called by muse, mutect2, varscan2
- KCNC3 | c.1419C>T p.G473= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1461828143, COSV65386877; called by muse, mutect2
- KNG1 | c.792C>T p.C264= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs201943382, COSV53980470; called by muse, mutect2, varscan2
- KNTC1 | c.60C>T p.V20= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs370631854, COSV59205385; called by muse, mutect2, varscan2
- LRP8 | c.2100T>C p.C700= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100035875; called by muse, mutect2, varscan2
- LRRK1 | c.51G>A p.P17= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs775634872, COSV52620384, COSV52626538; called by muse, mutect2, varscan2
- LTBP3 | c.2010C>T p.C670= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1393547117, COSV57238707; called by muse, mutect2, varscan2
- MKNK2 | c.798C>T p.S266= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1372730461, COSV99170200; called by muse, mutect2, varscan2
- MNAT1 | c.666G>A p.T222= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs143441995; called by muse, mutect2, varscan2
- MYH9 | c.468C>T p.T156= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs727503293, COSV99337556; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDRG1 | c.564G>A p.P188= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs755317968, COSV100105516; called by muse, mutect2, varscan2
- NKAPD1 | c.354T>C p.P118= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99735743; called by muse, mutect2, varscan2
- NMD3 | c.981A>T p.I327= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100664535; called by muse, mutect2, varscan2
- NSG1 | c.291C>T p.V97= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1279841991, COSV101207888; called by muse, mutect2, varscan2
- OMP | c.363C>T p.D121= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs782518243, COSV99581575; called by muse, mutect2, varscan2
- OTUD7A | c.669C>T p.H223= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs765724002, COSV100192431, COSV61037805; called by muse, mutect2, varscan2
- P2RX6 | c.280C>T p.L94= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV99488483; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2194A>C p.R732= (on ENST00000259318 / NM_001136562.3; = p.R963= on NM_007203.5) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99394489; called by muse, mutect2, varscan2
- PCDHGB4 | c.2031C>T p.P677= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs371220204; called by muse, mutect2, varscan2
- PCYOX1 | c.132T>C p.I44= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100036991; called by muse, mutect2, varscan2
- PDIA4 | c.1755C>T p.D585= (on ENST00000286091 / NM_001371244.1; = p.D584= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs761901124, COSV53723620, COSV53724257; called by muse, mutect2, varscan2
- PGLYRP2 | c.825C>T p.G275= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs374756265; called by muse, mutect2, varscan2
- PIK3C2A | c.4035T>C p.L1345= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV99790014; called by muse, mutect2, varscan2
- POTEF | c.243C>T p.G81= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs750656801, COSV100664440; called by muse, mutect2, varscan2
- PVR | c.342C>T p.R114= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1335015318, COSV99495614; called by muse, mutect2, varscan2
- QRICH2 | c.282C>T p.S94= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs138067412; called by muse, mutect2, varscan2
- RYR2 | c.4533G>A p.V1511= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100767078; called by muse, varscan2
- S100PBP | c.687T>C p.P229= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100758291; called by muse, mutect2, varscan2
- SAFB2 | c.321C>T p.D107= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs770714831, COSV99385255; called by muse, mutect2, varscan2
- SCAF8 | c.2172G>A p.P724= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs138080868; called by muse, mutect2, varscan2
- SGSM2 | c.1269C>T p.P423= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs779476038, COSV52158522; called by muse, mutect2, varscan2
- SLITRK6 | c.2310A>G p.G770= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101233157; called by muse, mutect2, varscan2
- SNX29 | c.1587G>A p.A529= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs368482101, COSV100026783; called by muse, mutect2, varscan2
- SPATA22 | c.180C>A p.A60= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52151803; called by muse, mutect2, varscan2
- SRP54 | c.528A>G p.V176= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV53740257; called by muse, mutect2, varscan2
- SRRM4 | c.1464G>T p.R488= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV57411289, COSV99937453; called by muse, mutect2, varscan2
- TADA2B | c.450G>A p.P150= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs764909836, COSV53826787; called by muse, varscan2
- TENM2 | c.2175C>T p.C725= (on ENST00000518659 / NM_001122679.2; = p.C493= on NM_001080428.3) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs747891977, COSV69145356; called by muse, mutect2, varscan2
- TET1 | c.2796T>C p.A932= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV101017418; called by muse, mutect2, varscan2
- TLE1 | c.1008C>T p.G336= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100916217; called by muse, mutect2, varscan2
- TMEM223 | c.180T>C p.A60= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99584832; called by muse, mutect2, varscan2
- TPD52L2 | c.30G>A p.L10= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99410469; called by muse, mutect2, varscan2
- TPGS1 | c.154C>T p.L52= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99298197; called by muse, mutect2, varscan2
- TUBE1 | c.1158C>T p.S386= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs267600764, COSV57889373; called by muse, mutect2, varscan2
- TUBGCP5 | c.2607C>T p.F869= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs570717920; ClinVar: likely benign; called by muse, mutect2, varscan2
- URI1 | c.1536G>A p.L512= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs767111698, COSV100368717; called by muse, mutect2, varscan2
- USP47 | c.3282C>T p.S1094= (on ENST00000399455 / NM_001372095.1; = p.S1006= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1466674399, COSV59693979, COSV59694818; called by muse, mutect2, varscan2
- VPS18 | c.369C>T p.Y123= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1450865557, COSV99592183; called by muse, mutect2, varscan2
- VWA8 | c.4668G>A p.E1556= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV65000646; called by muse, mutect2
- WDR3 | c.2520C>T p.N840= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs764543878, COSV60466669; called by muse, mutect2, varscan2
- YIF1A | c.366C>T p.Y122= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100268250; called by muse, mutect2, varscan2
- ZIM3 | c.777C>A p.A259= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54146662; called by muse, mutect2, varscan2
- ZMYND11 | c.93T>C p.I31= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100555740; called by muse, mutect2, varscan2
- ZNF268 | c.1170T>C p.C390= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99934661; called by muse, mutect2, varscan2
- ZNF518B | c.321G>A p.A107= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1287568633, COSV100456514; called by muse, mutect2, varscan2
- ZNF629 | c.549C>T p.C183= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1484191612, COSV52697538; called by muse, mutect2, varscan2
- ZNF672 | c.1152G>A p.L384= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100129015; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826769 T>G | 3'Flank (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- C1orf43 | c.*2G>A | 3'UTR (SNP) | VAF 13/65 reads (20%) | catalogued as rs375042634; called by muse, mutect2, varscan2
- CARD14 | c.1851+11C>T | Intron (SNP) | VAF 21/63 reads (33%) | catalogued as rs759126721, COSV100712440; called by muse, mutect2, varscan2
- CTBP2 | c.58+11792T>A | Intron (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100455995; called by muse, mutect2, varscan2
- MAPK3 | c.1017+50G>A | Intron (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99531111; called by muse, mutect2, varscan2
- MIR517A | n.34T>C | RNA (SNP) | VAF 20/90 reads (22%) | called by mutect2, varscan2
- PRR12 | chr19:49594532 C>T | 5'Flank (SNP) | VAF 8/28 reads (29%) | catalogued as rs1441246436, COSV99882213, COSV99882574; called by muse, mutect2
